Surgical pathology report (de-identified scan), TCGA case TCGA-BG-A0MU, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BG-A0MU-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: UTERUS, CERVIX, BILATERAL ADNEXA, TOTAL ABDOMINAL HYSTERECTOMY AND BILATERAL SALPINGO-OOPHORECTOMY -

- A. INVASIVE, WELL DIFFERENTIATED ENDOMETRIAL ADENOCARCINOMA, ENDOMETRIOID TYPE WITH MUCINOUS, SECRETORY AND SQUAMOUS DIFFERENTIATION, FIGO 1, NUCLEAR GRADE 1.
- B. TUMOR INVADERS 1.0 CM INTO 1.3 CM MYOMETRIUM.
- C. LYMPHOVASCULAR INVASION IS IDENTIFIED.
- D. COMPLEX ATYPICAL HYPERPLASIA.
- E. METASTATIC CARCINOMA INVOLVES FIMBRIATED END OF LEFT FALLOPIAN TUBE.
- F. CARCINOMA AND COMPLEX ATYPICAL HYPERPLASIA INVOLVE ADENOMYOSIS.
- G. CERVIX FREE OF TUMOR.
- H. ADENOMYOSIS.
- I. BILATERAL OVARIES AND RIGHT FALLOPIAN TUBE NEGATIVE FOR TUMOR.
- J. BILATERAL OVARIES WITH SURFACE ADHESIONS AND REACTIVE MESOTHELIAL PROLIFERATION WITH INFLAMMATORY CELLS.
- K. PELVIC WASH NEGATIVE.
- L. PATHOLOGIC STAGE: T2a N0 MX, FIGO IIA (CURRENT CLASSIFICATION).

PART 2: PELVIC LYMPH NODES, RIGHT, DISSECTION -
TWO LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/2).

PART 3: COMMON LYMPH NODE, RIGHT, DISSECTION -
ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 4: PARA-AORTIC LYMPH NODE, RIGHT, DISSECTION -
ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 5: PELVIC, LYMPH NODES, LEFT, DISSECTION -
FOUR LYMPH NODES, NEGATIVE FOR METASTATIC CARCINOMA (0/4).

PART 6: COMMON LYMPH NODE, LEFT, DISSECTION -
ONE LYMPH NODE, NEGATIVE FOR METASTATIC CARCINOMA (0/1).

PART 7: OMENTUM, OMENTECTOMY -
NEGATIVE FOR METASTATIC CARCINOMA.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY UTERINE ENDOMETRIAL TUMORS: HYSTERECTOMY SPECIMENS

TUMOR TYPE: Endometrioid adenocarcinoma, NOS

HISTOLOGIC GRADE (epithelial neoplasm) [combined architectural and nuclear]:

Well differentiated (FIGO 1)

ARCHITECTURAL GRADE: Well differentiated

NUCLEAR GRADE: Grade 1

TUMOR SIZE: Maximum dimension: 6.5 cm

PERCENT OF ENDOMETRIAL SURFACE INVOLVEMENT:

Anterior endomyometrium: 100 %, Posterior endomyometrium: 100 %
Greater than 1/2 thickness of myometrium

DEPTH OF INVASION**:

Yes

ANGIOLYMPHATIC INVASION:

PRE-NEOPLASTIC CONDITIONS:

Complex endometrial hyperplasia with atypia

LYMPH NODES POSITIVE:

Number of lymph nodes positive:: 0

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 9

T STAGE, PATHOLOGIC:

pT3a

N STAGE, PATHOLOGIC:

pN0

M STAGE, PATHOLOGIC:

PMX

FIGO STAGE:

IIIA

1CD-0-3

adenocarcinoma, endometrioid, NOS 8380/3

Site: endometrium C54.1

10/28/11

Source: NCI Genomic Data Commons file 444fb6a4-5909-4cab-9d4a-2a3b3d9ed3cd (TCGA-BG-A0MU.7162F7A7-7295-4736-B721-B13DAE006092.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).